Somatic mutation profile of tumor specimen TCGA-CI-6623-01B (aliquot TCGA-CI-6623-01B-11D-1826-10) from TCGA case TCGA-CI-6623, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 44.3 years (16,177 days).
Specimen TCGA-CI-6623-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 081d7199-8152-4cf3-9afa-c201edcd96f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CI-6623-10A (Blood Derived Normal), aliquot TCGA-CI-6623-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66b2142a-727d-47f5-94fa-c8aca2224371

The open-access MAF lists 82 somatic variants for this specimen: 59 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 20, Frame Shift Del 4, Splice Region 2, RNA 2, Nonsense Mutation 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SPART | c.696dup p.V233Cfs*8 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.644G>T p.S215I | Missense Mutation (SNP) | VAF 60/86 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782177, COSV52679681, COSV52686793, COSV52700292, COSV52891297; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.4708G>T p.V1570F | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs749958826, COSV67136170; called by muse, mutect2, varscan2
- AFM | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV99888975; called by muse, varscan2
- AHI1 | c.2801A>G p.N934S | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs546750537, COSV99663761; called by muse, mutect2, varscan2
- ALMS1 | c.2225A>T p.K742I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV52517087; called by muse, mutect2, varscan2
- AMER1 | c.3254C>T p.P1085L | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs56253937, COSV100367074; called by muse, mutect2, varscan2
- APC | c.3930del p.I1311Lfs*10 | Frame Shift Del (DEL) | VAF 30/83 reads (36%) | catalogued as CD106451, COSV57326113, COSV57375940; called by mutect2, pindel, varscan2
- C19orf18 | c.641A>C p.D214A | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV100072023; called by muse, mutect2, varscan2
- CAPN15 | c.2006G>A p.R669H | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749534366, COSV99562838; called by muse, mutect2, varscan2
- CAT | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53812364; called by muse, mutect2, varscan2
- CEP290 | c.4546G>C p.E1516Q | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV58354243; called by muse, mutect2, varscan2
- CPQ | c.86C>A p.S29Y | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55154714; called by muse, mutect2, varscan2
- CYP11A1 | c.562A>G p.K188E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.129); catalogued as COSV99166230; called by muse, mutect2, varscan2
- DNM1 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.595); catalogued as rs763830358, COSV100360343; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK2 | c.3844G>A p.E1282K | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs772944212, COSV56942701; called by muse, mutect2, varscan2
- DOCK3 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs754707449, COSV56538499; called by muse, mutect2, varscan2
- DYSF | c.5029C>T p.R1677C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.886); catalogued as rs771735871, COSV50308456; ClinVar: uncertain significance; called by mutect2, varscan2
- EDNRB | c.500C>T p.T167M (on ENST00000377211 / NM_001201397.1; = p.T77M on NM_000115.5) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1227502849, COSV57527236; called by muse, mutect2, varscan2
- EPS8L3 | c.275G>T p.R92L | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.452); catalogued as COSV62610123; called by muse, mutect2, varscan2
- FAM135A | c.2152C>G p.Q718E (on ENST00000370479 / NM_001351599.1; = p.Q505E on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as COSV52056328; called by muse, mutect2, varscan2
- FBN3 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs762486993, COSV54463872; called by muse, mutect2, varscan2
- FLG | c.5677G>A p.D1893N | Missense Mutation (SNP) | VAF 117/334 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.993); catalogued as rs780992659, COSV64245753; called by muse, mutect2, varscan2
- GJA8 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV53790777; called by muse, mutect2, varscan2
- IRX1 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV57361340; called by muse, mutect2, varscan2
- KCNMB2 | c.228C>T p.S76= | Splice Region (SNP) | VAF 27/89 reads (30%) | catalogued as rs770772310, COSV64202361; called by muse, varscan2
- MTHFS | c.251G>T p.R84L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV99358353; called by muse, mutect2, varscan2
- MXRA5 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 70/95 reads (74%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs368706975, COSV54224299; called by muse, mutect2, varscan2
- NLGN4X | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 65/112 reads (58%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs773637232, COSV52026038; called by muse, mutect2, varscan2
- NRIP1 | c.2536C>G p.L846V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV59659181; called by muse, mutect2, varscan2
- OR52N5 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as rs778217376, COSV100399779; called by muse, mutect2, varscan2
- PARVB | c.854G>A p.G285D | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58690698; called by muse, mutect2, varscan2
- PDZD2 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99226763; called by muse, mutect2
- PEG10 | c.839G>A p.R280H (on ENST00000482108 / NM_001040152.2; = p.R314H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as COSV71788507; called by muse, mutect2, varscan2
- PGK2 | c.4T>C p.S2P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV59164818; called by mutect2, varscan2
- PLXNB2 | c.4537G>A p.V1513M | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs371319008, COSV100834324; called by muse, mutect2, varscan2
- PSG1 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as rs201335145, COSV54947316; called by muse, mutect2, varscan2
- RB1CC1 | c.2470A>G p.T824A | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV99213020; called by muse, mutect2, varscan2
- RP1 | c.4598C>A p.A1533E | Missense Mutation (SNP) | VAF 69/127 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99608890; called by muse, mutect2, varscan2
- SASH1 | c.2525A>G p.D842G | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100821461; called by muse, varscan2
- SASH1 | c.2526C>G p.D842E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); catalogued as COSV100821462; called by muse, varscan2
- SASH1 | c.2527C>T p.L843F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV100821464; called by muse, varscan2
- SCRIB | c.4121del p.P1374Lfs*133 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as COSV100252652; called by mutect2, pindel, varscan2
- SHOX2 | c.637C>G p.Q213E (on ENST00000441443 / NM_006884.3; = p.Q237E on NM_003030.4) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.153); catalogued as COSV101273838; called by muse, mutect2, varscan2
- SIN3A | c.2006T>C p.L669P | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100845237; called by muse, mutect2, varscan2
- SLITRK1 | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.024); catalogued as COSV101000070; called by muse, mutect2, varscan2
- SOX5 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.269); catalogued as COSV100508266, COSV58640385; called by muse, mutect2, varscan2
- STK32B | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs373843574; called by muse, mutect2, varscan2
- U2AF1L4 | c.397C>T p.R133C (on ENST00000412391; = p.R94C on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755077639, COSV53073543, COSV99494974; called by mutect2, varscan2
- VWA3B | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs551578261, COSV68245165; called by muse, mutect2, varscan2
- ZFPM2 | c.2633C>T p.P878L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753602172, COSV101023525, COSV65872920; called by muse, mutect2, varscan2
- ZNF546 | c.1775G>A p.R592H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs559273469, COSV61257823; called by muse, mutect2, varscan2
- ZNF646 | c.4274C>T p.P1425L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99762676; called by muse, mutect2, varscan2
- ZSWIM3 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54849878; called by muse, mutect2, varscan2
- ANO9 | c.772-3dup | Splice Region (INS) | VAF 30/100 reads (30%) | called by mutect2, varscan2
- FZD9 | c.1651del p.R551Gfs*28 | Frame Shift Del (DEL) | VAF 52/148 reads (35%) | called by mutect2, pindel, varscan2
- KIAA0408 | c.1271del p.N424Ifs*97 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- SCAMP2 | c.844C>A p.L282I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); called by muse, mutect2
- ABCG1 | c.1584G>A p.P528= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs374817134, COSV100494537; called by muse, mutect2, varscan2
- BIRC6 | c.4164C>T p.I1388= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs570884165, COSV70203585; called by muse, mutect2, varscan2
- CADPS | c.678C>T p.D226= | Silent (SNP) | VAF 44/137 reads (32%) | catalogued as rs374797455; called by muse, mutect2, varscan2
- CELSR2 | c.3684C>T p.D1228= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as rs775455786, COSV54767615; called by muse, mutect2
- CUL9 | c.138G>A p.K46= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV99336071; called by muse, mutect2, varscan2
- FIGN | c.1272G>A p.S424= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs1347556599, COSV60763175; called by muse, mutect2, varscan2
- GPRASP2 | c.597G>A p.G199= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV59992081; called by muse, mutect2, varscan2
- GRIP2 | c.1749C>T p.L583= (on ENST00000619221; = p.L486= on NM_001080423.4) | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs762030891, COSV99817688; called by muse, mutect2, varscan2
- KCNV2 | c.1176C>T p.R392= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1181530530, COSV101172646; called by muse, mutect2, varscan2
- LRP2 | c.1548C>T p.A516= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs547538656, COSV55558690; called by muse, mutect2, varscan2
- MUC16 | c.4800C>A p.S1600= | Silent (SNP) | VAF 53/272 reads (19%) | catalogued as COSV101201763; called by muse, mutect2, varscan2
- MYH3 | c.1605G>T p.L535= | Silent (SNP) | VAF 45/158 reads (28%) | catalogued as COSV99878947; called by muse, mutect2, varscan2
- MYH7 | c.4077C>T p.R1359= | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as rs45523835, COSV62522390; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLXND1 | c.2199T>C p.C733= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV100140414; called by muse, mutect2, varscan2
- POTEH | c.354C>A p.G118= | Silent (SNP) | VAF 37/276 reads (13%) | catalogued as COSV100624641; called by muse, mutect2, varscan2
- POU6F1 | c.1101G>A p.A367= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs775700754, COSV61327492; called by muse, mutect2, varscan2
- TEX10 | c.2505C>T p.L835= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99318280; called by muse, mutect2, varscan2
- TTN | c.72618C>T p.T24206= (on ENST00000591111; = p.T16782= on NM_003319.4) | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs556181023, COSV60227074; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBQLNL | c.267C>A p.G89= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV100975573; called by muse, mutect2, varscan2
- ZFP42 | c.333C>T p.F111= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs1047170442, COSV58816461; called by muse, mutect2, varscan2
- HLA-L | n.776G>A | RNA (SNP) | VAF 123/288 reads (43%) | catalogued as rs772424902; called by muse, mutect2, varscan2
- MIR543 | n.45C>T | RNA (SNP) | VAF 54/227 reads (24%) | catalogued as rs745784066; called by muse, mutect2, varscan2
- PRSS3 | c.-6G>A | 5'UTR (SNP) | VAF 28/164 reads (17%) | catalogued as COSV61555042; called by muse, mutect2, varscan2
